Somatic mutation profile of tumor specimen ALCH-B2UH-TTP1-A (aliquot ALCH-B2UH-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.2 years (19,781 days).
Specimen ALCH-B2UH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27c51b0a-b0c5-475e-b36f-22d7a78aa462.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UH-NB1-A (Blood Derived Normal), aliquot ALCH-B2UH-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d962ed2e-e010-402e-b494-908ccbf02e94

The open-access MAF lists 963 somatic variants for this specimen: 629 protein-altering or splice-affecting, 209 silent, 125 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 550, Silent 209, Intron 52, Nonsense Mutation 45, RNA 30, 5'UTR 15, 3'UTR 14, Splice Site 12, 5'Flank 10, Splice Region 9, Frame Shift Del 8, Frame Shift Ins 4.

Variants (750 of 963; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 43/289 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SERPINA1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28931568, CM900179; ClinVar: other / pathogenic; called by mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 46/381 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs550451294, COSV99067430, COSV99285825; called by mutect2, varscan2
- ACTL6B | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as CM1512355, COSV50516399; called by muse, mutect2, varscan2
- ADAMTS20 | c.1808G>T p.R603L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV67137622; called by muse, mutect2, varscan2
- ADAMTS20 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs577775989; called by muse, mutect2
- ADCY2 | c.1578G>T p.T526= | Splice Region (SNP) | VAF 12/102 reads (12%) | catalogued as COSV57901389; called by muse, mutect2
- ADCYAP1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs769489887; called by muse, mutect2
- ADGRE1 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs528274667, COSV51672205, COSV51674313; called by muse, mutect2, varscan2
- AFF2 | c.2776C>A p.R926S | Missense Mutation (SNP) | VAF 45/624 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.282); catalogued as COSV54000517, COSV54002779; called by muse, mutect2
- AHCYL2 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); catalogued as COSV61484835; called by muse, mutect2
- AICDA | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 81/729 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.12); catalogued as COSV57563759; called by muse, mutect2, varscan2
- ALPG | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200199364, COSV104402087, COSV54964645; called by muse, mutect2, varscan2
- AMPH | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57761502; called by muse, mutect2
- ANK2 | c.3505G>T p.G1169C | Missense Mutation (SNP) | VAF 50/470 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763340139; called by muse, mutect2
- ANKRD17 | c.6529G>T p.A2177S | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100429849; called by muse, mutect2, varscan2
- AP2A1 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62820527; called by muse, mutect2, varscan2
- AP2A2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs368541164; called by muse, mutect2
- APOBEC1 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.516); catalogued as COSV57548377; called by muse, mutect2, varscan2
- ARFGEF2 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 62/646 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs374268118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP39 | c.2189C>G p.P730R | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99431654; called by muse, mutect2, varscan2
- ARID1A | c.4379G>T p.G1460V | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100252621, COSV61389619; called by muse, mutect2
- ATP10B | c.4360C>T p.R1454* | Nonsense Mutation (SNP) | VAF 26/166 reads (16%) | catalogued as rs200376757, COSV100515622; called by muse, mutect2
- BAHCC1 | c.1594C>G p.P532A | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.253); catalogued as COSV100311531; called by muse, mutect2, varscan2
- BARX2 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 66/562 reads (12%) | catalogued as COSV55650946; called by muse, mutect2, varscan2
- BCL9L | c.3331G>C p.A1111P | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52685927; called by muse, mutect2
- C1orf94 | c.1366C>A p.L456M (on ENST00000488417 / NM_001134734.2; = p.L266M on NM_032884.5) | Missense Mutation (SNP) | VAF 39/451 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs755851680; called by muse, mutect2
- C4orf54 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1353578745, COSV72766678; called by muse, mutect2, varscan2
- C7orf26 | c.339G>T p.L113F | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs771728522; called by muse, mutect2
- CAMK2A | c.1318G>T p.A440S (on ENST00000348628 / NM_171825.2; = p.A451S on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/808 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); catalogued as rs374924411; called by muse, mutect2
- CASS4 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as rs781242436; called by muse, mutect2, varscan2
- CD177 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65121808; called by muse, mutect2, varscan2
- CDH1 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55744869; called by muse, mutect2
- CDH1 | c.1666G>T p.V556L | Missense Mutation (SNP) | VAF 50/638 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV55733260; called by muse, mutect2
- CEP85 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV53332400; called by muse, mutect2, varscan2
- CFAP46 | c.4570G>C p.A1524P | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as COSV63953149; called by muse, mutect2, varscan2
- CFHR5 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 19/349 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56823478; called by muse, mutect2
- CIP2A | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1236665663; called by muse, mutect2, varscan2
- CLCA2 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV65286344; called by muse, mutect2
- CLCN2 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55599287; called by muse, mutect2, varscan2
- CNKSR1 | c.2011G>T p.A671S (on ENST00000374253 / NM_001297647.2; = p.A664S on NM_006314.3) | Missense Mutation (SNP) | VAF 56/398 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs770390491, COSV58792147; called by muse, mutect2, varscan2
- CNNM4 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 62/578 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs768361992; called by muse, mutect2, varscan2
- CNTNAP4 | c.2789G>T p.G930V | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56678297; called by muse, mutect2
- COL1A2 | c.1223del p.P408Lfs*274 | Frame Shift Del (DEL) | VAF 76/679 reads (11%) | catalogued as COSV51954317; called by mutect2, pindel, varscan2
- CPA3 | c.982-1G>T p.X328_splice | Splice Site (SNP) | VAF 26/269 reads (10%) | catalogued as COSV56044686; called by muse, mutect2, varscan2
- CPED1 | c.2254T>A p.C752S | Missense Mutation (SNP) | VAF 62/647 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV60014785; called by muse, mutect2
- CRACD | c.558del p.G187Afs*62 | Frame Shift Del (DEL) | VAF 17/166 reads (10%) | catalogued as COSV51717610; called by mutect2, varscan2
- CSMD1 | c.6655G>T p.G2219C (on ENST00000520002; = p.G2218C on NM_033225.6) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59366547; called by muse, mutect2, varscan2
- CSMD3 | c.8356G>C p.D2786H (on ENST00000297405 / NM_001363185.1; = p.D2617H on NM_052900.3) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs747333485, COSV52183071, COSV52285643; called by muse, mutect2, varscan2
- CT47B1 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 60/786 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as rs749873024; called by muse, mutect2
- CUL3 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52366153, COSV52371279; called by muse, mutect2, varscan2
- CYP27A1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV51467030; called by muse, mutect2, varscan2
- CYRIB | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101310130; called by muse, mutect2, varscan2
- DCAF4L2 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV60476700; called by muse, mutect2, varscan2
- DCC | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1410195305, COSV59122668; called by muse, mutect2, varscan2
- DCC | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1399430363; called by muse, mutect2
- DGKB | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV99342603; called by muse, mutect2
- DKK2 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 36/322 reads (11%) | catalogued as COSV53395716; called by muse, mutect2, varscan2
- DLGAP1 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59796187; called by mutect2, varscan2
- DMRT2 | c.1333C>A p.L445M | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV99426196; called by muse, mutect2, varscan2
- DOCK2 | c.4085T>C p.I1362T | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs972184894; called by muse, mutect2
- DOK6 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as COSV101234663; called by muse, mutect2, varscan2
- DRP2 | c.2768G>T p.S923I | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV67871050; called by muse, mutect2
- DTNA | c.1684C>A p.R562S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as COSV99315197; called by muse, mutect2, varscan2
- DUSP6 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 25/395 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV54378773; called by muse, mutect2
- DZIP1L | c.1047G>T p.M349I | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748818108; called by muse, mutect2, varscan2
- ERN2 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56838378; called by muse, mutect2
- ESYT2 | c.785G>C p.R262T (on ENST00000613624; = p.R186T on NM_020728.3) | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51753486; called by muse, mutect2, varscan2
- FAM126A | c.-31C>G | Splice Region (SNP) | VAF 30/321 reads (9%) | catalogued as rs1214963061; called by muse, mutect2
- FAM217B | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV62564252; called by muse, mutect2
- FAM90A10P | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 110/416 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs749335112; called by muse, mutect2, varscan2
- FOXD4L5 | c.217C>A p.H73N | Missense Mutation (SNP) | VAF 62/874 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs771008006; called by muse, mutect2
- FOXP2 | c.1228del p.H410Tfs*14 | Frame Shift Del (DEL) | VAF 65/605 reads (11%) | catalogued as COSV63483938; called by mutect2, pindel, varscan2
- FSCB | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV61218503; called by muse, mutect2
- FSHR | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV58619761; called by muse, mutect2
- GAD2 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 18/202 reads (9%) | catalogued as COSV52159019; called by muse, mutect2
- GAL3ST3 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs750464463, COSV100361060; called by muse, mutect2
- GALNT17 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61176649, COSV61194625; called by muse, mutect2, varscan2
- GATA6 | c.909G>T p.M303I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as COSV52526285; called by muse, mutect2
- GFAP | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1455211354, COSV53653366; called by muse, mutect2, varscan2
- GPAM | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs910929866; called by muse, mutect2, varscan2
- GPNMB | c.199A>T p.M67L | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV51699326; called by muse, mutect2
- GPR20 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs574585646, COSV66684086; called by muse, mutect2, varscan2
- GPR50 | c.1469C>A p.S490Y | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV54439422; called by muse, mutect2
- GRM4 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.965); catalogued as COSV65210342; called by muse, mutect2, varscan2
- GSG1L2 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 25/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68010973; called by muse, mutect2
- HECW1 | c.2229C>A p.N743K | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.206); catalogued as COSV67820802; called by muse, mutect2
- HENMT1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368196522, COSV64229898; called by muse, mutect2, varscan2
- HFM1 | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as rs1348600114; called by muse, mutect2
- HOXC6 | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99679016; called by muse, mutect2, varscan2
- HS3ST2 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 93/687 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs780005383; called by muse, mutect2, varscan2
- HTR1A | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1366606163, COSV100108823; called by muse, mutect2, varscan2
- HTR4 | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 30/630 reads (5%) | catalogued as COSV100087684; called by muse, mutect2
- IGHV3-33 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 25/448 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs374974779; called by muse, mutect2
- ITGA1 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as COSV50881851; called by muse, mutect2, varscan2
- JUP | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 23/458 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as COSV60277490; called by muse, mutect2
- KCNA5 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 81/667 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52904171; called by muse, mutect2, varscan2
- KCNK2 | c.1097C>G p.S366W (on ENST00000444842 / NM_001017425.3; = p.S351W on NM_014217.4) | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67204202; called by muse, mutect2, varscan2
- KCNN3 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777932235, COSV55220412, COSV99679076; called by muse, mutect2, varscan2
- KEL | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 175/974 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs143144958; called by muse, mutect2, varscan2
- KEL | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 127/616 reads (21%) | catalogued as COSV62337876; called by muse, mutect2, varscan2
- KIF2B | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV52133907; called by muse, mutect2
- KLHL34 | c.227C>G p.S76W | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750266650; called by muse, mutect2
- KMT2C | c.2573G>T p.W858L | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs111493987, COSV51367709; called by muse, mutect2, varscan2
- KRTAP9-3 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 104/882 reads (12%) | SIFT deleterious (0.01); catalogued as rs372133664; called by mutect2, varscan2
- LCE1C | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100908446; called by muse, mutect2
- LDB3 | c.1385C>A p.T462N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.452); catalogued as COSV53939449; called by muse, mutect2, varscan2
- LHFPL6 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.166); catalogued as COSV65448644; called by muse, mutect2, varscan2
- LIG3 | c.1614G>T p.V538= | Splice Region (SNP) | VAF 6/70 reads (9%) | catalogued as rs1314348533; called by muse, mutect2
- LPA | c.3622C>T p.P1208S | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60296425, COSV60303973; called by muse, mutect2, varscan2
- LPAR3 | c.1055C>T p.T352I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs752040306, COSV65453265; called by muse, mutect2
- LYPD6B | c.136A>T p.N46Y (on ENST00000409029 / NM_001317004.1; = p.N70Y on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99700457; called by muse, mutect2
- MAGEB18 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100305455; called by muse, mutect2
- MAP2 | c.3130G>T p.G1044C | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV52311005; called by muse, mutect2
- MAP3K10 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs755866907; called by muse, mutect2, varscan2
- MAP9 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs997356593; called by muse, varscan2
- MCF2 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV58488655; called by muse, mutect2
- MED13L | c.4399G>T p.V1467L | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV56132007; called by muse, mutect2, varscan2
- MMP11 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs376641686; called by muse, mutect2, varscan2
- MMP3 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782147410; called by muse, mutect2, varscan2
- MOXD1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60947962; called by muse, mutect2, varscan2
- MUC16 | c.25502C>A p.S8501Y | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.153); catalogued as rs763464577, COSV67448477, COSV67465137; called by muse, mutect2, varscan2
- MUC16 | c.22622C>A p.T7541N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1381754135, COSV67481548; called by muse, varscan2
- NAV3 | c.1705A>G p.I569V | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs376491041; called by muse, mutect2, varscan2
- NCKAP1L | c.3296T>A p.L1099Q | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320481671, COSV53207253; called by muse, mutect2, varscan2
- NFKB2 | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1425541702, COSV50065894; called by muse, mutect2
- NPVF | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV56060047; called by muse, mutect2
- NUP188 | c.3429+1G>T p.X1143_splice | Splice Site (SNP) | VAF 16/284 reads (6%) | catalogued as COSV65361118; called by muse, mutect2
- OBSCN | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.197); catalogued as rs1325773542; called by muse, mutect2, varscan2
- OOEP | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.21); catalogued as rs746053383, COSV64859413, COSV64859578; called by muse, mutect2, varscan2
- OR10R2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV63768498; called by muse, mutect2, varscan2
- OR1S1 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100515311; called by muse, mutect2
- OR2T1 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV63541388; called by muse, mutect2, varscan2
- OR2T12 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58777180; called by muse, mutect2
- OR6C3 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs372567255; called by muse, mutect2, varscan2
- OR6T1 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 33/524 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.217); catalogued as COSV58308432; called by muse, mutect2
- OTOGL | c.4113G>T p.M1371I (on ENST00000547103; = p.M1362I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV101509123; called by muse, mutect2, varscan2
- PALB2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs371582757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH11X | c.2241C>A p.H747Q | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100012224; called by muse, mutect2, varscan2
- PCDH15 | c.2144C>A p.P715Q | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57261025; called by muse, mutect2
- PCDH8 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.41); catalogued as COSV58815034; called by muse, mutect2
- PCDHA8 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as rs1176105427; called by muse, mutect2
- PCDHB6 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1186236708; called by muse, mutect2
- PCLO | c.2824G>T p.A942S | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61624279; called by muse, mutect2
- PDHA2 | c.22del p.R8Afs*3 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | catalogued as COSV54782413; called by mutect2, pindel, varscan2
- PEX13 | c.912A>T p.K304N | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1460703366; called by muse, mutect2
- PI4K2B | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV53513192; called by muse, mutect2
- PIEZO2 | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV57456447; called by muse, mutect2
- PIK3CG | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV63247857, COSV63248082; called by muse, mutect2, varscan2
- PIR | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 20/230 reads (9%) | catalogued as COSV62917841; called by muse, mutect2
- PLD1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763233081; called by muse, mutect2, varscan2
- PLEKHS1 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV63055827; called by muse, mutect2
- PLXDC1 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100195480, COSV59553692; called by muse, mutect2, varscan2
- POLR3C | c.148-1G>T p.X50_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV61936596; called by muse, varscan2
- PPL | c.4805C>T p.A1602V | Missense Mutation (SNP) | VAF 130/801 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749710304; called by muse, mutect2, varscan2
- PRDM16 | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 33/468 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377255144; ClinVar: uncertain significance; called by muse, mutect2
- PRKAR1B | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 21/354 reads (6%) | catalogued as COSV100816614; called by muse, mutect2
- PSG7 | c.1061G>C p.C354S | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331039187; called by muse, mutect2
- PTGDR | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 56/380 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60094633; called by muse, mutect2, varscan2
- PTPRT | c.3880G>T p.G1294W | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.222); catalogued as COSV61985978; called by muse, mutect2
- RB1CC1 | c.2327G>C p.R776P | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50243752; called by muse, mutect2, varscan2
- RBM10 | c.1160G>T p.R387M | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as CS1414400, COSV61311565; called by muse, mutect2, varscan2
- RBM20 | c.2933T>A p.L978H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1367589873; called by muse, mutect2, varscan2
- RC3H2 | c.3361G>T p.G1121C | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV61799779; called by muse, mutect2, varscan2
- RGSL1 | c.2444G>T p.R815L | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV54260972; called by muse, mutect2
- RPA4 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 47/373 reads (13%) | catalogued as COSV100235274; called by muse, mutect2, varscan2
- RYR2 | c.12327G>T p.M4109I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.184); catalogued as rs1465872180; called by muse, mutect2, varscan2
- SCRG1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.999); catalogued as rs757953805; called by muse, mutect2
- SERPINA7 | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59666610; called by muse, mutect2
- SERPINB5 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV66975965; called by muse, varscan2
- SH3RF3 | c.1384G>T p.V462F | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV58693341; called by muse, mutect2, varscan2
- SIGLEC12 | c.956C>A p.P319H (on ENST00000291707 / NM_053003.4; = p.P201H on NM_033329.2) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.553); catalogued as COSV52460143; called by muse, mutect2, varscan2
- SIGLECL1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs755599473; called by muse, mutect2
- SLC12A1 | c.1685C>A p.A562E | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66792535; called by muse, mutect2, varscan2
- SLC22A2 | c.1253G>C p.C418S | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs755035249; called by muse, mutect2, varscan2
- SLC23A2 | c.799G>C p.G267R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57776068; called by muse, mutect2, varscan2
- SLC29A4 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99786900; called by muse, mutect2
- SLC9A9 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774762131; called by muse, mutect2, varscan2
- SMAD2 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50995927, COSV50996806; called by muse, mutect2
- SMARCC2 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99911109; called by muse, mutect2
- SMARCC2 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200020901, COSV99911115; called by muse, mutect2
- SPANXD | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 35/526 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65152662; called by muse, mutect2
- SPDL1 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV54669994; called by muse, mutect2, varscan2
- SPEN | c.677G>C p.R226P | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65359398; called by muse, mutect2, varscan2
- STAU2 | c.205G>C p.A69P (on ENST00000524300 / NM_001164380.2; = p.A37P on NM_014393.2) | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV62480786; called by muse, mutect2, varscan2
- STMN2 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99626851; called by muse, mutect2, varscan2
- SYT5 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 24/138 reads (17%) | catalogued as COSV62831551; called by muse, mutect2, varscan2
- TAZ | c.141G>T p.R47S | Missense Mutation (SNP) | VAF 37/509 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV50009991; called by muse, mutect2
- TBX2 | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1401962009; called by muse, mutect2
- TCHHL1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1207590189, COSV100916576; called by muse, mutect2, varscan2
- TDRD1 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV52594574; called by muse, mutect2
- TECTB | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488799257; called by muse, mutect2, varscan2
- TERT | c.1049T>A p.L350Q | Missense Mutation (SNP) | VAF 185/1346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486854283; called by muse, mutect2, varscan2
- TG | c.5450A>T p.Q1817L | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV55083497; called by muse, mutect2
- TLN2 | c.7567G>T p.A2523S | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1319616187; called by muse, mutect2, varscan2
- TMEM176B | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs1322465517; called by muse, mutect2
- TMEM185B | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV101446796; called by muse, mutect2, varscan2
- TRIM25 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1190288587, COSV100380966; called by muse, mutect2
- TRIM58 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as rs1295610802; called by muse, mutect2
- TUT4 | c.3232-1G>T p.X1078_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99932998; called by muse, mutect2, varscan2
- USH2A | c.4520C>A p.S1507* | Nonsense Mutation (SNP) | VAF 15/186 reads (8%) | catalogued as COSV56343034; called by muse, mutect2
- UXS1 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 63/469 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51683264; called by muse, mutect2, varscan2
- VGF | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.688); catalogued as rs868451839; called by muse, mutect2
- WASHC2A | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 113/834 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1296497284; called by muse, mutect2, varscan2
- WT1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 36/668 reads (5%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.023); catalogued as COSV100188171; called by muse, mutect2
- XDH | c.3756G>T p.K1252N | Missense Mutation (SNP) | VAF 64/546 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV65149002; called by muse, mutect2, varscan2
- XPO6 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58970063; called by mutect2, varscan2
- ZAN | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 74/584 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV61818667; called by muse, mutect2, varscan2
- ZAN | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV104418992; called by muse, mutect2, varscan2
- ZDHHC7 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 22/616 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV58212303; called by muse, mutect2
- ZFHX4 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs1239475431, COSV51482400; called by muse, mutect2, varscan2
- ZFHX4 | c.8650C>G p.Q2884E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.653); catalogued as COSV51444798; called by muse, mutect2, varscan2
- ZNF479 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 30/672 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV58639805; called by muse, mutect2
- ZNF521 | c.3305G>A p.S1102N | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV100831228; called by muse, mutect2
- ZNF716 | c.486C>A p.C162* | Nonsense Mutation (SNP) | VAF 19/153 reads (12%) | catalogued as COSV70783393; called by muse, mutect2, varscan2
- ABCA2 | c.3159C>G p.F1053L (on ENST00000614293; = p.F1023L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- AC004593.2 | c.801G>A p.K267= | Splice Region (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- ACADSB | c.435A>T p.L145F | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2
- ACSM4 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT1 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- ADAM12 | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ADAM19 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 32/309 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ADGRA3 | c.3357G>T p.Q1119H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2
- ADGRA3 | c.3037G>T p.G1013W | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRD2 | c.1202T>A p.M401K | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- AHCYL1 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- AHNAK2 | c.15454G>T p.A5152S | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.274); called by muse, mutect2
- AKAP13 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2
- AKAP6 | c.6080C>G p.T2027R | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AKR1B15 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, varscan2
- ALPK2 | c.5201G>T p.R1734M | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ALPK2 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- AMER3 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AMOTL2 | c.2032G>A p.G678R | Missense Mutation (SNP) | VAF 34/709 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); called by muse, mutect2
- ANK1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APBA2 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 37/590 reads (6%) | called by muse, mutect2
- APEX2 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APLNR | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2
- APOB | c.2302A>T p.K768* | Nonsense Mutation (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.1611C>A p.D537E (on ENST00000393797 / NM_001319850.2; = p.D518E on NM_032496.4) | Missense Mutation (SNP) | VAF 59/467 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARIH1 | c.805-2A>T p.X269_splice | Splice Site (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- ARX | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- ASIC2 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP13A2 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 97/712 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ATP1B4 | c.1018G>T p.V340F (on ENST00000218008 / NM_001142447.3; = p.V336F on NM_012069.5) | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.696); called by muse, mutect2
- BACE2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.018); called by muse, mutect2
- BCL9 | c.4164G>T p.M1388I | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9L | c.1070C>A p.T357K | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.173); called by muse, mutect2
- BIRC6 | c.13543C>G p.P4515A | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BPNT1 | c.274T>A p.W92R | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- BST1 | c.124C>G p.H42D | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BTBD3 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C1QC | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1QTNF8 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C4orf17 | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- C7orf25 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2
- CADPS | c.2190C>A p.Y730* | Nonsense Mutation (SNP) | VAF 62/489 reads (13%) | called by muse, mutect2, varscan2
- CAPN10 | c.1663del p.R555Afs*47 | Frame Shift Del (DEL) | VAF 100/692 reads (14%) | called by mutect2, pindel, varscan2
- CAPN15 | c.2037G>T p.W679C | Missense Mutation (SNP) | VAF 48/419 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.301); called by muse, mutect2
- CCDC190 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.178); called by muse, mutect2
- CCN1 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCND2 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CD163 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CD1C | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CD3G | c.439+1G>T p.X147_splice | Splice Site (SNP) | VAF 47/393 reads (12%) | called by muse, mutect2, varscan2
- CD4 | c.374-3C>T | Splice Region (SNP) | VAF 47/594 reads (8%) | called by muse, mutect2
- CDH1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 34/359 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2
- CDH12 | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, varscan2
- CDH9 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- CDK18 | c.1269-1G>T p.X423_splice (on ENST00000506784 / NM_212503.3; = p.X393_splice on NM_002596.4) | Splice Site (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- CDR1 | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, mutect2
- CEACAM18 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CEP135 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.153); called by muse, mutect2
- CFAP91 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFH | c.2102G>T p.W701L | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHL1 | c.746C>A p.S249* (on ENST00000397491 / NM_001253387.1; = p.S265* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- CHST1 | c.804C>A p.D268E | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.333); called by muse, mutect2
- CLCA2 | c.1537A>C p.T513P | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CLEC3A | c.142+1G>T p.X48_splice (on ENST00000651443; = p.X39_splice on NM_005752.6) | Splice Site (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 8/224 reads (4%) | called by muse, mutect2
- COL11A2 | c.3859G>T p.D1287Y (on ENST00000341947 / NM_080680.3; = p.D1180Y on NM_080679.2) | Missense Mutation (SNP) | VAF 90/810 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL5A3 | c.1587G>T p.M529I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- COL6A1 | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 130/705 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A3 | c.4882C>A p.P1628T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CPE | c.790+2T>C p.X264_splice | Splice Site (SNP) | VAF 34/149 reads (23%) | called by muse, varscan2
- CPLX4 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2
- CPNE3 | c.1045G>C p.A349P | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPS1 | c.1768T>A p.Y590N | Missense Mutation (SNP) | VAF 66/547 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSMD3 | c.7199C>A p.P2400H (on ENST00000297405 / NM_001363185.1; = p.P2296H on NM_052900.3) | Missense Mutation (SNP) | VAF 45/423 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CSN1S1 | c.328A>T p.N110Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CUL5 | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.413); called by muse, mutect2
- CUX1 | c.274G>T p.V92L (on ENST00000292535 / NM_181552.4; = p.V103L on NM_001913.5) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- CUX1 | c.2443G>T p.G815C | Missense Mutation (SNP) | VAF 48/445 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- CXCL1 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 30/383 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2
- CYP11B2 | c.1279C>A p.R427S | Missense Mutation (SNP) | VAF 118/828 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DAB2 | c.1965T>A p.F655L | Missense Mutation (SNP) | VAF 52/622 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DBX2 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCLK2 | c.1294G>T p.G432* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- DDX19A | c.144T>G p.D48E | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- DEFB4A | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 83/667 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DHX57 | c.1840_1841del p.A614* | Frame Shift Del (DEL) | VAF 42/407 reads (10%) | called by mutect2, pindel
- DLGAP2 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DLGAP3 | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2
- DLL4 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DMGDH | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DMXL2 | c.8756dup p.R2920* | Frame Shift Ins (INS) | VAF 65/581 reads (11%) | called by mutect2, pindel, varscan2
- DNMT3L | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 72/423 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK11 | c.4907C>T p.S1636L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- DPRX | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DPYD | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC1H1 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); called by muse, mutect2
- DYNC2H1 | c.10087A>T p.N3363Y | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- EDN3 | c.51A>T p.A17= | Splice Region (SNP) | VAF 41/470 reads (9%) | called by muse, mutect2
- EIF2B2 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 25/524 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.315); called by muse, mutect2
- EMILIN3 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EMX1 | c.751A>T p.K251* | Nonsense Mutation (SNP) | VAF 44/328 reads (13%) | called by muse, mutect2, varscan2
- ENO4 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EPHA7 | c.2289T>A p.N763K | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- ERCC3 | c.278A>T p.Y93F | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ERN2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 81/704 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ETV3L | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 35/368 reads (10%) | called by muse, mutect2
- EVC2 | c.3493G>T p.E1165* | Nonsense Mutation (SNP) | VAF 36/168 reads (21%) | called by muse, varscan2
- F5 | c.4601G>A p.S1534N | Missense Mutation (SNP) | VAF 54/421 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAM170B | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.48); called by muse, mutect2
- FAM171B | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM186A | c.5794C>A p.P1932T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FAM83D | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- FASTKD3 | c.470G>C p.S157T | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.068); called by muse, mutect2
- FLNA | c.5204C>A p.P1735H (on ENST00000369850 / NM_001110556.2; = p.P1727H on NM_001456.3) | Missense Mutation (SNP) | VAF 31/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FLNA | c.1338C>G p.Y446* | Nonsense Mutation (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- FLT4 | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FNDC1 | c.4361C>T p.T1454I | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FSCB | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- FSIP2 | c.2415G>C p.L805F | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.099); called by muse, mutect2
- FUT1 | c.1046G>T p.W349L | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS2L2 | c.997C>A p.L333M | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2
- GCDH | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 31/626 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GCN1 | c.4187G>T p.G1396V | Missense Mutation (SNP) | VAF 88/634 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GEM | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 123/828 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GFPT2 | c.1698G>T p.M566I | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.174); called by muse, mutect2
- GLS | c.173G>T p.W58L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- GMFG | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 49/396 reads (12%) | called by muse, mutect2, varscan2
- GNB1 | c.203+1G>T p.X68_splice | Splice Site (SNP) | VAF 17/194 reads (9%) | called by muse, mutect2
- GPR26 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR45 | c.761A>T p.Q254L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GPR83 | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- GRID2 | c.1626C>A p.D542E | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- GRIK1 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GRIK2 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- GRIK4 | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRIN2B | c.2885A>T p.Y962F | Missense Mutation (SNP) | VAF 130/1360 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.845); called by muse, mutect2
- GRM1 | c.1116G>T p.W372C | Missense Mutation (SNP) | VAF 79/545 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GUCY1A1 | c.1768A>T p.K590* | Nonsense Mutation (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- HDAC9 | c.3189G>T p.M1063I (on ENST00000441542 / NM_178425.3; = p.M1060I on NM_178423.3) | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- HEPACAM2 | c.1363G>T p.A455S (on ENST00000394468 / NM_001039372.4; = p.A443S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- HGF | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA7 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 44/708 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOXD10 | c.193del p.Q65Kfs*5 | Frame Shift Del (DEL) | VAF 48/438 reads (11%) | called by mutect2, pindel, varscan2
- HTR4 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 30/627 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHA1 | c.915G>T p.W305C | Missense Mutation (SNP) | VAF 86/1473 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV1-17 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, varscan2
- IGLV2-8 | c.54G>T p.W18C | Missense Mutation (SNP) | VAF 48/694 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- IPO11 | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.199); called by muse, mutect2
- IQCA1 | c.519G>T p.R173S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQSEC2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 140/745 reads (19%) | called by muse, mutect2, varscan2
- IQSEC3 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ITGAL | c.2782C>A p.Q928K | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- ITPR2 | c.3716A>T p.H1239L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- JARID2 | c.3094G>C p.A1032P | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- KCND2 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCND3 | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- KCNH7 | c.3049T>C p.W1017R | Missense Mutation (SNP) | VAF 22/489 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- KCNT2 | c.2992A>G p.N998D | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1549L | c.4037G>A p.S1346N (on ENST00000321505; = p.S1643N on NM_012194.3) | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2
- KIF26A | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- KIRREL1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.942); called by muse, mutect2
- KLK14 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 55/503 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KMT2B | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KRBA1 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 83/388 reads (21%) | called by muse, mutect2, varscan2
- KRT33B | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 47/417 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT4 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 90/629 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KRT85 | c.643G>C p.V215L | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, mutect2
- KRTAP20-1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 40/262 reads (15%) | PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KRTAP21-1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- LCE1C | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2
- LILRA1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.22); called by muse, mutect2
- LIN37 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- LMNA | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 111/818 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- LMX1B | c.1052-1G>T p.X351_splice (on ENST00000373474 / NM_001174147.2; = p.X344_splice on NM_002316.4) | Splice Site (SNP) | VAF 58/432 reads (13%) | called by muse, mutect2, varscan2
- LPAR3 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRIT2 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 74/470 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAGEA12 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 39/866 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEA12 | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 38/869 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEA6 | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 56/606 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- MAGEB6B | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); called by muse, mutect2
- MAP2 | c.4276A>G p.R1426G | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MAPK6 | c.1043A>G p.H348R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- MAPK8IP3 | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MARCO | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MCOLN1 | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 90/1086 reads (8%) | called by muse, mutect2
- ME3 | c.204A>C p.E68D | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- MEGF11 | c.283A>T p.S95C | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- MEGF8 | c.5989G>T p.G1997W (on ENST00000251268 / NM_001271938.2; = p.G1930W on NM_001410.3) | Missense Mutation (SNP) | VAF 50/825 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- MFAP4 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MKX | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- MLIP | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2
- MRC1 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 44/700 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2
- MRC1 | c.3248C>A p.S1083Y | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.122); called by muse, mutect2
- MROH2A | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); called by muse, mutect2
- MROH8 | c.600G>T p.R200S | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MSX1 | c.874A>C p.T292P | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- MTOR | c.4443G>A p.M1481I | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2
- MUC16 | c.3046G>T p.E1016* | Nonsense Mutation (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.7207C>A p.L2403I | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYBPC1 | c.834T>A p.D278E (on ENST00000550270 / NM_206820.2; = p.D303E on NM_002465.4) | Missense Mutation (SNP) | VAF 48/468 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYBPC1 | c.1580A>T p.D527V (on ENST00000550270 / NM_206820.2; = p.D552V on NM_002465.4) | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- MYH1 | c.1793A>T p.D598V | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- NAV3 | c.1351G>C p.A451P | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- NAV3 | c.2753C>A p.S918Y | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NCOA3 | c.3604G>T p.G1202C | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- NEB | c.16560A>T p.K5520N | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NECAB2 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- NEFM | c.2593G>T p.G865W | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEURL4 | c.3097G>T p.G1033W | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2
- NFASC | c.3330G>C p.W1110C (on ENST00000339876 / NM_001378329.1; = p.W1039C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NKD2 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.634); called by muse, mutect2
- NKX3-2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2
- NOC2L | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL4L | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NPSR1 | c.1046C>A p.S349Y | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NR1H4 | c.365C>A p.P122H (on ENST00000551379 / NM_001206993.2; = p.P112H on NM_005123.4) | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- NRG3 | c.1839G>T p.M613I (on ENST00000404547 / NM_001370084.1; = p.M589I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NRK | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- NRXN2 | c.2311G>T p.A771S | Missense Mutation (SNP) | VAF 44/684 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- NSUN4 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- NSUN4 | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- OCA2 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 66/796 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- OGFOD2 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.23); called by muse, mutect2
- OR10W1 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 31/300 reads (10%) | called by muse, mutect2, varscan2
- OR14J1 | c.755dup p.A253Cfs*4 | Frame Shift Ins (INS) | VAF 26/204 reads (13%) | called by mutect2, varscan2
- OR14J1 | c.756delinsCC p.A253Rfs*4 | Frame Shift Ins (INS) | VAF 19/201 reads (9%) | called by mutect2*, pindel, varscan2*
- OR2F2 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OR2G3 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.324); called by muse, mutect2
- OR4C16 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR4C46 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- OR51A7 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.033); called by muse, mutect2
- OR51B6 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- OR51Q1 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- OR5A1 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OR5B17 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR5J2 | c.409T>A p.S137T | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by mutect2, varscan2
- OR5M10 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- OR6N2 | c.713_721del p.F238_T240del | In Frame Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- OR6Q1 | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, mutect2
- OR6T1 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR9A2 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OS9 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.493); called by muse, mutect2
- OTOG | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2
- OTUD4 | c.1391A>G p.N464S (on ENST00000447906 / NM_001366057.1; = p.N399S on NM_001102653.1) | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAH | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PAPSS1 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- PARVG | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- PARVG | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 53/485 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDH15 | c.3763G>A p.V1255M | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDH15 | c.1784G>T p.R595M | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDH19 | c.665T>A p.V222D | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- PCDHA13 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 131/1054 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PCDHB5 | c.1776C>A p.D592E | Missense Mutation (SNP) | VAF 52/1004 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA3 | c.1318C>G p.L440V | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PCDHGB3 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PCDHGB4 | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGB5 | c.467T>A p.V156E | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.045); called by muse, mutect2
- PCMTD2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PCNT | c.9698C>A p.P3233Q | Missense Mutation (SNP) | VAF 44/675 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- PCSK7 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PDCD11 | c.1226A>T p.E409V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PDE3A | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); called by muse, mutect2
- PEAK3 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGLYRP2 | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PHF3 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PIGT | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L3 | c.2036C>G p.P679R | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLA2G2E | c.415A>T p.T139S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- PLAC1 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLAU | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2
- PLCZ1 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.058); called by muse, varscan2
- PLEC | c.8338G>T p.E2780* (on ENST00000322810 / NM_201380.4; = p.E2670* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 107/955 reads (11%) | called by muse, mutect2, varscan2
- PLK5 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PNLIPRP2 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PNPLA5 | c.343C>G p.R115G | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- POLN | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.486); called by muse, mutect2
- POM121L2 | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- POTEC | c.1012G>T p.G338* | Nonsense Mutation (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- POTEJ | c.2335C>A p.R779S | Missense Mutation (SNP) | VAF 42/533 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- POU3F4 | c.338C>G p.A113G | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- PPARGC1A | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- PPIP5K2 | c.3179G>T p.C1060F | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PPP1R3A | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 86/647 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PPP4R3C | c.1264C>A p.Q422K | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2
- PRAG1 | c.2468G>C p.R823P | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PRDM14 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRKCG | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 87/677 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRLR | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSG9 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by mutect2, varscan2
- PTGER2 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2
- PTPRO | c.2989T>A p.Y997N (on ENST00000281171 / NM_030667.3; = p.Y969N on NM_002848.4) | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PXDNL | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PXYLP1 | c.1394G>C p.G465A | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RAB44 | c.2800G>T p.A934S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2
- RAP1A | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2
- RBM46 | c.1518T>A p.Y506* | Nonsense Mutation (SNP) | VAF 43/502 reads (9%) | called by muse, mutect2
- RELN | c.4113C>G p.I1371M | Missense Mutation (SNP) | VAF 45/425 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- RET | c.373G>T p.V125F | Missense Mutation (SNP) | VAF 78/558 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RET | c.2581G>T p.G861W | Missense Mutation (SNP) | VAF 51/944 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RGS12 | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS22 | c.1173C>G p.S391R | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RP1L1 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 140/637 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- RRP12 | c.3523G>T p.D1175Y | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2
- RTP5 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 58/496 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, varscan2
- RYBP | c.619A>T p.K207* | Nonsense Mutation (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- SAGE1 | c.1206C>A p.S402R | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- SAP30 | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SCAMP4 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SCART1 | c.2903A>T p.E968V | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- SEC31A | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SERINC2 | c.278G>T p.G93V (on ENST00000373709 / NM_178865.5; = p.G97V on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SETD2 | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SEZ6 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SHANK1 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 91/606 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SHCBP1 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SHQ1 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2
- SI | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SIGLEC10 | c.1562G>T p.C521F | Missense Mutation (SNP) | VAF 100/644 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SKI | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 49/392 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC49A4 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC4A3 | c.2009C>A p.P670H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SLC7A14 | c.73A>T p.R25W | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLCO1B1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT1 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2
- SLITRK1 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 23/527 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SMAP2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SMARCAD1 | c.2925A>G p.I975M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, varscan2
- SMARCAL1 | c.1298dup p.S434Vfs*2 | Frame Shift Ins (INS) | VAF 42/380 reads (11%) | called by mutect2, pindel, varscan2
- SMG7 | c.680A>G p.Q227R | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2
- SMKR1 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated, low confidence (0.45); called by muse, mutect2
- SNRPB | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SORBS1 | c.452C>T p.S151F (on ENST00000361941 / NM_001034954.2; = p.S119F on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORBS2 | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SP9 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 49/605 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPEF2 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SPEG | c.1936C>G p.P646A | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SPON1 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- SPTBN4 | c.4028G>C p.W1343S | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SSH1 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSU72P8 | c.144A>T p.R48S | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ST6GAL2 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | PolyPhen benign (0); called by muse, mutect2
- STAT6 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 42/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STC1 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- SULF1 | c.813_816del p.H271Qfs*15 | Frame Shift Del (DEL) | VAF 16/192 reads (8%) | called by mutect2, pindel
- SYNJ1 | c.2765A>C p.K922T | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SYT16 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- SYTL4 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.2767G>T p.G923C | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM2 | c.5057C>A p.T1686N (on ENST00000518659 / NM_001122679.2; = p.T1447N on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- TEX13C | c.2395C>A p.P799T | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT deleterious (0.04); called by muse, mutect2
- TEX51 | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- THOP1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- THSD7B | c.4516G>A p.G1506S (on ENST00000272643; = p.G1504S on NM_001316349.2) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- TIAM2 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 59/442 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLX3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- TMEM132C | c.3239A>T p.E1080V | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TMEM132D | c.828C>A p.H276Q | Missense Mutation (SNP) | VAF 57/532 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM168 | c.1013A>T p.N338I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TMEM185A | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 34/799 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.242); called by muse, mutect2
- TMEM52B | c.334G>T p.A112S (on ENST00000381923 / NM_001079815.1; = p.A92S on NM_153022.4) | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); called by muse, mutect2
- TMLHE | c.752C>G p.P251R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TNRC18 | c.2084G>T p.G695V | Missense Mutation (SNP) | VAF 72/1312 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TRAK1 | c.1139G>C p.G380A (on ENST00000327628 / NM_001349247.2; = p.G322A on NM_014965.5) | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TRIM2 | c.4G>A p.A2T (on ENST00000437508; = p.A29T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TRIM29 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRIM37 | c.616+1G>T p.X206_splice | Splice Site (SNP) | VAF 15/252 reads (6%) | called by muse, mutect2
- TRMT1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 23/417 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2
- TRPC4 | c.1751C>T p.T584I | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); called by muse, mutect2
- TRPM5 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2
- TRPM6 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 63/609 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TRPV5 | c.762G>T p.V254= | Splice Region (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.80236C>A p.P26746T (on ENST00000591111; = p.P19322T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.21355G>C p.V7119L (on ENST00000591111; = p.V6192L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/127 reads (8%) | PolyPhen benign (0.007); called by muse, mutect2
- TXNRD1 | c.797A>T p.Y266F (on ENST00000525566 / NM_001093771.3; = p.Y168F on NM_003330.4) | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- UNC13C | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | called by muse, varscan2
- UNC45B | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- UNC80 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- UNC80 | c.8452C>A p.L2818I | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- USF1 | c.8+6T>G | Splice Region (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- USP15 | c.1898G>T p.C633F (on ENST00000280377 / NM_001351159.2; = p.C604F on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- USP49 | c.15A>T p.K5N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- VKORC1L1 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS25 | c.253+3G>T | Splice Region (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- VPS41 | c.276G>T p.L92F | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- VWF | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 78/699 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- WDR90 | c.5217G>T p.E1739D | Missense Mutation (SNP) | VAF 76/665 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WEE2 | c.1345C>G p.P449A | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- WT1 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.426); called by muse, mutect2
- XAB2 | c.1374G>T p.K458N | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- XPNPEP2 | c.1533G>T p.L511F | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YTHDF2 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ZBTB8B | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF114 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ZNF174 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 32/433 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF18 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF318 | c.1057G>T p.G353* | Nonsense Mutation (SNP) | VAF 27/317 reads (9%) | called by muse, mutect2
- ZNF326 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- ZNF43 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF479 | c.552T>A p.H184Q | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZNF534 | c.1088G>T p.G363V (on ENST00000332323 / NM_001143939.3; = p.G350V on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- ZNF536 | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF536 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF710 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF721 | c.1735G>T p.G579C (on ENST00000338977; = p.G591C on NM_133474.4) | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF792 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 37/211 reads (18%) | called by muse, mutect2, varscan2
- ZNF804B | c.51C>G p.Y17* | Nonsense Mutation (SNP) | VAF 36/335 reads (11%) | called by muse, mutect2, varscan2
- ZNF835 | c.1565G>T p.C522F | Missense Mutation (SNP) | VAF 63/891 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); called by muse, mutect2
- ZNF845 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 35/258 reads (14%) | called by muse, mutect2, varscan2
- ZNF853 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF98 | c.1454C>A p.T485N | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- ZNF99 | c.702T>A p.C234* | Nonsense Mutation (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- ZRANB3 | c.2150C>A p.P717Q | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ABCA9 | c.4306C>T p.L1436= | Silent (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- ABCC11 | c.3318G>A p.T1106= | Silent (SNP) | VAF 34/342 reads (10%) | catalogued as rs879161986; called by muse, mutect2
- ABLIM1 | c.96G>C p.S32= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as rs778681393, COSV53316806; called by muse, mutect2, varscan2
- AC109583.1 | c.138G>A p.A46= | Silent (SNP) | VAF 92/577 reads (16%) | catalogued as COSV59350286; called by mutect2, varscan2
- AC138647.1 | c.324G>T p.L108= | Silent (SNP) | VAF 41/262 reads (16%) | called by muse, mutect2, varscan2
- ADAM11 | c.418C>A p.R140= | Silent (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- ADAMTS20 | c.1242T>C p.D414= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.3156G>T p.T1052= | Silent (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- ADAT3 | c.900G>A p.L300= | Silent (SNP) | VAF 99/821 reads (12%) | called by muse, mutect2, varscan2
- AHNAK | c.4602G>C p.L1534= | Silent (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
- ANKS1A | c.2457C>A p.L819= | Silent (SNP) | VAF 29/428 reads (7%) | catalogued as rs766999402, COSV64464791; called by muse, mutect2
- APC2 | c.2097C>A p.P699= | Silent (SNP) | VAF 46/486 reads (9%) | catalogued as COSV52016040; called by muse, mutect2, varscan2
- APOBEC3A | c.357C>T p.H119= | Silent (SNP) | VAF 52/772 reads (7%) | catalogued as rs201179078; called by muse, mutect2
- ARHGAP22 | c.1428G>T p.S476= | Silent (SNP) | VAF 26/286 reads (9%) | catalogued as COSV99985391; called by muse, mutect2
- ASB18 | c.855G>A p.E285= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ASB6 | c.252G>A p.A84= | Silent (SNP) | VAF 45/208 reads (22%) | called by muse, mutect2, varscan2
- ASTN2 | c.816G>T p.R272= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- ATP10B | c.4359C>A p.R1453= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV59160736; called by muse, mutect2, varscan2
- ATP11A | c.1437C>T p.H479= | Silent (SNP) | VAF 14/254 reads (6%) | catalogued as rs893316748; called by muse, mutect2
- ATXN1 | c.2172C>G p.A724= | Silent (SNP) | VAF 25/247 reads (10%) | catalogued as COSV55230086; called by muse, mutect2, varscan2
- BDKRB2 | c.286C>T p.L96= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs752521547; called by mutect2, varscan2
- BRSK2 | c.1104G>T p.P368= | Silent (SNP) | VAF 20/247 reads (8%) | called by muse, mutect2
- BTBD17 | c.816G>C p.S272= | Silent (SNP) | VAF 59/406 reads (15%) | called by muse, mutect2, varscan2
- C1QC | c.546G>C p.L182= | Silent (SNP) | VAF 36/343 reads (10%) | catalogued as rs755640714; called by muse, mutect2
- CACNA1I | c.5340C>A p.G1780= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs930862683, COSV60813063; called by muse, mutect2, varscan2
- CACNA2D1 | c.3252C>A p.I1084= (on ENST00000356253 / NM_001366867.1; = p.I1072= on NM_000722.4) | Silent (SNP) | VAF 18/466 reads (4%) | catalogued as COSV100666959, COSV62388760; called by muse, mutect2
- CAMK2B | c.585G>T p.V195= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- CAPN15 | c.1050G>T p.T350= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as rs1042271265; called by muse, mutect2
- CCDC141 | c.1860A>T p.T620= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV55369005; called by muse, mutect2
- CD248 | c.528A>T p.P176= | Silent (SNP) | VAF 33/193 reads (17%) | called by muse, mutect2, varscan2
- CDR2L | c.549G>T p.L183= | Silent (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
- CEP128 | c.174G>T p.V58= | Silent (SNP) | VAF 34/379 reads (9%) | called by muse, mutect2
- CEP162 | c.2916A>T p.L972= | Silent (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- CES1 | c.78G>T p.V26= | Silent (SNP) | VAF 82/982 reads (8%) | called by muse, mutect2
- CFAP43 | c.936G>A p.Q312= | Silent (SNP) | VAF 15/179 reads (8%) | catalogued as COSV53378682; called by muse, mutect2
- CHERP | c.396A>G p.T132= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- CLEC7A | c.198C>A p.T66= | Silent (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- COL5A3 | c.5079G>A p.Q1693= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as COSV53410248; called by muse, mutect2, varscan2
- CSMD3 | c.2454A>G p.S818= (on ENST00000297405 / NM_001363185.1; = p.S714= on NM_052900.3) | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.2178T>A p.T726= (on ENST00000297405 / NM_001363185.1; = p.T622= on NM_052900.3) | Silent (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- CSN1S1 | c.327C>T p.Y109= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- CTAGE6 | c.879G>T p.L293= | Silent (SNP) | VAF 17/48 reads (35%) | called by mutect2, varscan2
- CTNNB1 | c.501G>T p.V167= | Silent (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- CTSG | c.315C>A p.I105= | Silent (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- CTTNBP2 | c.132C>T p.L44= | Silent (SNP) | VAF 46/498 reads (9%) | catalogued as rs768883336; called by muse, mutect2
- CUBN | c.3777G>C p.L1259= | Silent (SNP) | VAF 63/491 reads (13%) | called by muse, mutect2, varscan2
- CYBRD1 | c.627G>T p.L209= | Silent (SNP) | VAF 38/259 reads (15%) | called by muse, mutect2, varscan2
- DBH | c.1155C>A p.I385= | Silent (SNP) | VAF 68/450 reads (15%) | called by muse, mutect2, varscan2
- DCHS1 | c.7995G>T p.L2665= | Silent (SNP) | VAF 63/668 reads (9%) | called by muse, mutect2
- DENND5B | c.30G>T p.P10= | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2142C>T p.A714= | Silent (SNP) | VAF 121/533 reads (23%) | catalogued as rs776821647, COSV68105333; called by muse, mutect2, varscan2
- DZIP3 | c.2676G>T p.V892= | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as COSV64312637; called by muse, mutect2
- EARS2 | c.258G>T p.G86= | Silent (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- EFTUD2 | c.1533G>T p.G511= | Silent (SNP) | VAF 16/262 reads (6%) | catalogued as COSV68183706; called by muse, mutect2
- EOMES | c.303G>T p.P101= | Silent (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- EPHB1 | c.2937A>T p.S979= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- ERC1 | c.2889G>T p.R963= (on ENST00000360905 / NM_178040.4; = p.R935= on NM_178039.4) | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- FAM71F1 | c.333G>T p.L111= | Silent (SNP) | VAF 28/427 reads (7%) | catalogued as COSV100170992; called by muse, mutect2
- FARSB | c.993G>C p.L331= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- FBH1 | c.1431A>C p.A477= (on ENST00000362091 / NM_178150.3; = p.A528= on NM_032807.4) | Silent (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- FBLN1 | c.1254G>T p.T418= | Silent (SNP) | VAF 68/1012 reads (7%) | catalogued as COSV53052649; called by muse, mutect2
- FBN3 | c.8190G>T p.L2730= | Silent (SNP) | VAF 20/237 reads (8%) | called by muse, mutect2
- FGA | c.2154C>T p.T718= | Silent (SNP) | VAF 27/341 reads (8%) | called by muse, mutect2
- FGG | c.258G>T p.L86= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- FLNA | c.693G>A p.Q231= | Silent (SNP) | VAF 32/436 reads (7%) | called by muse, mutect2
- FOXF2 | c.120C>A p.A40= | Silent (SNP) | VAF 28/283 reads (10%) | catalogued as COSV99453077; called by muse, mutect2
- FRAS1 | c.9429G>T p.G3143= | Silent (SNP) | VAF 25/235 reads (11%) | called by muse, mutect2, varscan2
- FRMPD3 | c.1365C>G p.A455= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as rs1359114820; called by muse, mutect2
- FSCB | c.543C>A p.A181= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV61217680; called by muse, mutect2, varscan2
- FSHR | c.175C>A p.R59= | Silent (SNP) | VAF 27/392 reads (7%) | catalogued as COSV58626201, COSV58628208; called by muse, mutect2
- FSIP2 | c.567A>G p.L189= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- GABBR1 | c.2175C>A p.L725= | Silent (SNP) | VAF 50/484 reads (10%) | called by muse, mutect2
- GABPA | c.1329G>T p.L443= | Silent (SNP) | VAF 37/215 reads (17%) | called by muse, mutect2, varscan2
- GABRA3 | c.90G>T p.G30= | Silent (SNP) | VAF 25/174 reads (14%) | catalogued as COSV64805346; called by muse, mutect2, varscan2
- GABRG1 | c.1347C>T p.T449= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as rs368289518; called by muse, mutect2
- GCNT1 | c.480T>C p.D160= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as COSV65058769; called by muse, mutect2, varscan2
- GFPT2 | c.550C>T p.L184= | Silent (SNP) | VAF 17/290 reads (6%) | called by muse, mutect2
- GMCL2 | c.522C>T p.V174= | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- GPR137 | c.888G>T p.R296= | Silent (SNP) | VAF 23/332 reads (7%) | called by muse, mutect2
- GUK1 | c.6G>T p.S2= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV100451836; called by muse, mutect2, varscan2
- HEY1 | c.225G>T p.L75= | Silent (SNP) | VAF 39/365 reads (11%) | called by muse, mutect2, varscan2
- HNRNPF | c.294G>A p.K98= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- HOXC9 | c.480C>T p.P160= | Silent (SNP) | VAF 34/251 reads (14%) | catalogued as rs1194693194; called by muse, mutect2, varscan2
- HSPG2 | c.6264G>T p.G2088= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- HTR3A | c.1422C>T p.I474= | Silent (SNP) | VAF 65/547 reads (12%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.258C>A p.V86= | Silent (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2, varscan2
- IRX4 | c.333G>T p.A111= | Silent (SNP) | VAF 57/654 reads (9%) | catalogued as COSV51470662; called by muse, mutect2
- ITGAV | c.2913C>T p.I971= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- KCNH2 | c.570C>T p.A190= | Silent (SNP) | VAF 127/471 reads (27%) | called by mutect2, varscan2
- KERA | c.975C>A p.L325= | Silent (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- KIF3C | c.1443G>T p.L481= | Silent (SNP) | VAF 63/495 reads (13%) | called by muse, mutect2, varscan2
- KRT7 | c.1011C>T p.A337= | Silent (SNP) | VAF 48/372 reads (13%) | catalogued as rs368567294; called by muse, mutect2, varscan2
- KRT77 | c.1389C>A p.I463= | Silent (SNP) | VAF 53/388 reads (14%) | catalogued as rs776967209, COSV100527316; called by muse, mutect2, varscan2
- L1CAM | c.2715C>G p.P905= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- LAMB4 | c.1242T>C p.P414= | Silent (SNP) | VAF 22/258 reads (9%) | called by muse, mutect2
- LAP3 | c.426G>C p.V142= | Silent (SNP) | VAF 44/562 reads (8%) | called by muse, mutect2
- LDB3 | c.1386C>G p.T462= | Silent (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- LHX8 | c.978G>T p.L326= | Silent (SNP) | VAF 46/376 reads (12%) | called by muse, mutect2, varscan2
- LMF1 | c.264A>G p.R88= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, varscan2
- LPA | c.4410G>T p.S1470= | Silent (SNP) | VAF 37/384 reads (10%) | catalogued as COSV100307411; called by muse, mutect2
- LRRC14B | c.414G>T p.L138= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- LRRC66 | c.2502A>T p.A834= | Silent (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- LRRK2 | c.7417T>C p.L2473= | Silent (SNP) | VAF 29/258 reads (11%) | catalogued as rs910431246; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRTM3 | c.261C>A p.L87= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- MAP1S | c.1803G>T p.P601= | Silent (SNP) | VAF 65/541 reads (12%) | called by muse, mutect2, varscan2
- MAPRE2 | c.891G>C p.L297= | Silent (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2
- MCM3 | c.651G>A p.K217= (on ENST00000229854 / NM_001366374.2; = p.K207= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 16/455 reads (4%) | called by muse, mutect2
- MGAM | c.2277A>G p.L759= | Silent (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- MMP3 | c.552C>A p.A184= | Silent (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.207C>A p.A69= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs777988527, COSV57105980; called by muse, mutect2, varscan2
- MROH2A | c.3729G>T p.P1243= | Silent (SNP) | VAF 32/344 reads (9%) | catalogued as COSV67682859; called by muse, mutect2
- MUC16 | c.24579A>T p.T8193= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- MUC16 | c.21135T>A p.L7045= | Silent (SNP) | VAF 29/269 reads (11%) | called by muse, mutect2, varscan2
- MUC5AC | c.147C>A p.P49= | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- NDST4 | c.2406C>T p.P802= | Silent (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2
- NEB | c.10614G>T p.R3538= | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2
- NEIL3 | c.1287A>T p.I429= | Silent (SNP) | VAF 40/252 reads (16%) | called by muse, mutect2
- NEK11 | c.933G>A p.Q311= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV63580070, COSV63582820; called by muse, mutect2
- NFATC3 | c.81G>T p.P27= | Silent (SNP) | VAF 15/237 reads (6%) | catalogued as rs896199666; called by muse, mutect2
- NINL | c.2367C>T p.P789= | Silent (SNP) | VAF 45/335 reads (13%) | catalogued as rs577554820, COSV99626250; called by muse, mutect2, varscan2
- NOBOX | c.1488C>A p.P496= | Silent (SNP) | VAF 30/294 reads (10%) | called by muse, mutect2
213 further variants in this file (0 protein-altering or splice-affecting, 88 silent, 125 other) are not listed here.
